Gene-level copy-number profile of tumor specimen TCGA-60-2712-01A from TCGA case TCGA-60-2712, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.8 years (29,131 days).
Specimen TCGA-60-2712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3361ed5c-7ada-4bc7-8038-d6b93fd6f69b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2712-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/012b578d-ffbe-4dd3-be36-6be537ec5436

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 2: 14,802; copy number 3: 17,831; copy number 4: 24,219; copy number 5: 987; copy number 6: 149; copy number 7: 1; copy number 8: 1,727; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-60-2712-01): tumor purity 0.36, ploidy 3.34, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:234,329,483–236,754,363, 30 genes: RPS20P12, AC097713.2, AC097713.1, LINC01891, HSPE1P9, ARL4C, LINC01173, AC104394.1, AC010148.1, SH3BP4, AC114814.1, CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P, Y_RNA, GBX2, AC019068.1, ASB18, RNU1-31P, IQCA1, AC093915.1, IQCA1-AS1, RPL3P5, ACKR3, AC084030.1.
- chr9:20,532,552–23,438,700, 66 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:63,151,114–63,151,320, 1 gene, copy number 9: AC022726.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
